Somatic mutation profile of tumor specimen TCGA-CG-5718-01A (aliquot TCGA-CG-5718-01A-11D-1600-08) from TCGA case TCGA-CG-5718, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 78.7 years (28,763 days).
Specimen TCGA-CG-5718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f0761a4-9704-4201-ab1f-c358af85283f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5718-10A (Blood Derived Normal), aliquot TCGA-CG-5718-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25873f8d-a85d-496a-b8d1-c1c72cd556c1

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1886del p.L629* | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | catalogued as rs863224817; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.4239C>A p.N1413K | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59388291; called by muse, mutect2, varscan2
- ACOT12 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.086); catalogued as COSV56895613, COSV56896007, COSV56898607; called by muse, mutect2, varscan2
- ACSL1 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55663626; called by muse, mutect2, varscan2
- ACTRT2 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101007612, COSV65759598; called by muse, mutect2, varscan2
- ADCY2 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV57878787; called by muse, mutect2, varscan2
- ALCAM | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60250076; called by muse, mutect2, varscan2
- ARHGAP31 | c.1034A>T p.K345I | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV51794668; called by muse, mutect2, varscan2
- ATP10A | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1440723193, COSV63518992; called by muse, mutect2
- ATXN10 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as COSV53297641; called by muse, mutect2, varscan2
- BIRC6 | c.8099C>G p.S2700* | Nonsense Mutation (SNP) | VAF 84/332 reads (25%) | catalogued as COSV70201039; called by muse, mutect2, varscan2
- CASKIN2 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV58596948; called by muse, mutect2, varscan2
- CHD3 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs749330456, COSV57876525; called by muse, mutect2, varscan2
- CHD5 | c.3406C>T p.R1136C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52417296; called by muse, mutect2, varscan2
- CNGA3 | c.673+2T>A p.X225_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as COSV55625206; called by muse, mutect2, varscan2
- CNKSR2 | c.1487C>G p.S496* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV54258871; called by muse, mutect2
- CNNM2 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1043614377, COSV63999453; called by muse, mutect2, varscan2
- DCAF12L1 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1176083541, COSV64421966, COSV64422026; called by muse, mutect2, varscan2
- DHRS3 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66108356; called by muse, mutect2, varscan2
- DMRT1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs764065635, COSV66522100; called by muse, mutect2, varscan2
- DZIP1L | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987675067, COSV59521667; called by muse, mutect2, varscan2
- EPG5 | c.2276A>T p.N759I | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as COSV56351256; called by muse, mutect2, varscan2
- EPHA8 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV51272951; called by muse, mutect2, varscan2
- GPR55 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs770175579, COSV67407985; called by muse, mutect2, varscan2
- GRM1 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746660819, COSV51174083; called by muse, mutect2, varscan2
- HECTD1 | c.3998A>G p.K1333R | Missense Mutation (SNP) | VAF 95/154 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.137); catalogued as rs761550936, COSV67947117; called by muse, mutect2, varscan2
- HLA-A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as rs41546018, COSV65139114, COSV65141540; called by muse, varscan2
- HLA-F | c.674G>T p.W225L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV52576082; called by muse, mutect2, varscan2
- IGFBP1 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs776233561, COSV51874913; called by muse, mutect2, varscan2
- ITPR1 | c.4535T>C p.L1512P (on ENST00000354582; = p.L1497P on NM_002222.7) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56986659; called by muse, mutect2, varscan2
- KCNT2 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54086256; called by muse, mutect2, varscan2
- MAP2K7 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67608621; called by muse, mutect2
- MC5R | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV61254920; called by muse, mutect2, varscan2
- MRTFB | c.2525C>T p.P842L (on ENST00000571589 / NM_001365412.2; = p.P792L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147357478; called by muse, mutect2, varscan2
- MUC15 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1565110153, COSV55555220; called by muse, mutect2, varscan2
- OR11A1 | c.528C>A p.D176E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV65821123; called by muse, mutect2, varscan2
- OR51D1 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV62914341; called by muse, mutect2, varscan2
- PCDHGA6 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV53917739, COSV54050495; called by muse, mutect2, varscan2
- PCLO | c.5728G>T p.A1910S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV61642341; called by muse, mutect2, varscan2
- PCSK2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs567308071, COSV52729317; called by muse, mutect2, varscan2
- PEAK1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs1460934683, COSV56937783; called by muse, mutect2, varscan2
- PIEZO2 | c.7440+1G>A p.X2480_splice | Splice Site (SNP) | VAF 62/230 reads (27%) | catalogued as rs777712782, COSV53290749; called by muse, mutect2, varscan2
- PLXNB3 | c.5572T>G p.C1858G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV62798382; called by muse, mutect2
- PTPRC | c.2221T>C p.W741R | Missense Mutation (SNP) | VAF 176/974 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61414013, COSV61415809; called by muse, mutect2, varscan2
- RELN | c.8567G>T p.C2856F | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59009925; called by muse, mutect2, varscan2
- RHBDD2 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as rs782137859, COSV50086965; called by muse, mutect2, varscan2
- RHOBTB2 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs763030083, COSV52392974; called by muse, mutect2, varscan2
- RHOXF1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1484612375, COSV54294908; called by muse, mutect2, varscan2
- SIPA1L1 | c.3326C>A p.A1109D | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV62170992; called by muse, mutect2, varscan2
- SIX3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM086936, COSV53227613; called by muse, mutect2, varscan2
- SLIT2 | c.1511T>A p.L504Q | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV56577077, COSV99881474; called by muse, mutect2
- SMG1 | c.9968A>G p.D3323G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV67172336; called by muse, mutect2, varscan2
- SSH2 | c.4099A>C p.S1367R | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV52174173; called by muse, mutect2
- SUCLG1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1225454425, COSV67265320; called by muse, mutect2, varscan2
- SYNJ1 | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as COSV59150320; called by muse, mutect2, varscan2
- TMTC2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs573420920, COSV58268300; called by muse, mutect2, varscan2
- TNRC6B | c.4750A>G p.K1584E (on ENST00000454349 / NM_001162501.2; = p.K1474E on NM_015088.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.965); catalogued as COSV57299029; called by muse, mutect2, varscan2
- TTC3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV61291790, COSV61294494; called by muse, mutect2, varscan2
- YTHDC1 | c.2107C>T p.R703C (on ENST00000344157 / NM_001031732.4; = p.R685C on NM_133370.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV60010862; called by muse, mutect2, varscan2
- ZNF264 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs746840418, COSV54042293; called by muse, mutect2, varscan2
- ZSCAN31 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV60181138; called by muse, mutect2, varscan2
- APOB | c.3565dup p.M1189Nfs*14 | Frame Shift Ins (INS) | VAF 46/226 reads (20%) | called by mutect2, varscan2
- CTAGE6 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.386); called by mutect2, varscan2
- USP21 | c.1426dup p.S476Kfs*20 | Frame Shift Ins (INS) | VAF 20/135 reads (15%) | called by mutect2, varscan2
- ADD3 | c.27G>A p.V9= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs776523907, COSV53322427, COSV53323116; called by muse, mutect2, varscan2
- ARHGAP21 | c.4494G>A p.T1498= | Silent (SNP) | VAF 127/455 reads (28%) | catalogued as rs769009600, COSV57602514; called by muse, mutect2, varscan2
- ATP6AP1 | c.609C>A p.I203= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV63895831; called by muse, mutect2, varscan2
- CD22 | c.2220C>T p.A740= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV50049863, COSV50055705; called by muse, mutect2, varscan2
- CDC42BPB | c.2199C>T p.I733= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as COSV63475444; called by muse, mutect2, varscan2
- CFHR4 | c.1626G>A p.G542= (on ENST00000367416 / NM_001201551.2; = p.G296= on NM_006684.5) | Silent (SNP) | VAF 102/244 reads (42%) | catalogued as rs373680214; called by muse, mutect2
- GDPD4 | c.1038C>T p.V346= | Silent (SNP) | VAF 62/221 reads (28%) | catalogued as rs1216822560, COSV60020185; called by muse, mutect2, varscan2
- KCNA4 | c.945G>A p.L315= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV60253405; called by muse, mutect2, varscan2
- KCNJ2 | c.795C>T p.S265= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as COSV54662204; called by muse, mutect2, varscan2
- LILRA5 | c.783C>T p.Y261= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs201689439, COSV56642880; called by muse, mutect2, varscan2
- MACC1 | c.1587T>A p.S529= | Silent (SNP) | VAF 76/362 reads (21%) | catalogued as COSV60543870; called by muse, mutect2, varscan2
- MEIS1 | c.804G>A p.K268= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV55488251, COSV99715342; called by muse, mutect2, varscan2
- MKKS | c.1155G>A p.E385= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV61399049; called by muse, mutect2, varscan2
- PCLO | c.1143T>G p.P381= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV61642355; called by muse, mutect2, varscan2
- PKHD1 | c.3018C>T p.I1006= | Silent (SNP) | VAF 98/231 reads (42%) | catalogued as COSV61881482, COSV61885035; called by muse, mutect2, varscan2
- RFPL2 | c.663C>T p.A221= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs781538355, COSV50711940; called by muse, mutect2, varscan2
- RNASE4 | c.183G>A p.K61= | Silent (SNP) | VAF 57/360 reads (16%) | catalogued as COSV59012467; called by muse, mutect2, varscan2
- SYNE1 | c.13554C>T p.R4518= (on ENST00000367255 / NM_182961.4; = p.R4447= on NM_033071.3) | Silent (SNP) | VAF 77/298 reads (26%) | catalogued as rs115535983; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- ZNF300 | c.1266C>T p.S422= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV51037189; called by muse, mutect2, varscan2
- ZNF595 | c.1704A>G p.E568= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV59550940, COSV59553966; called by muse, mutect2, varscan2
- ZSWIM3 | c.1338G>A p.P446= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs778001548, COSV54848483; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827194 A>G | 3'Flank (SNP) | VAF 71/337 reads (21%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+55del | Intron (DEL) | VAF 36/156 reads (23%) | called by mutect2, pindel, varscan2
- TCHHL1 | c.-1G>A | 5'UTR (SNP) | VAF 36/168 reads (21%) | catalogued as COSV100916533; called by muse, mutect2, varscan2
